Somatic mutation profile of tumor specimen 0DVCFJ from CCDI case PBCMKS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 16.6 years (6,061 days).
Specimen 0DVCFJ: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c45edaa3-8e73-4108-b771-3e7f2086c2db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cce27cfb-2ef8-49a9-a7b9-73799ac187f0

The open-access MAF lists 32 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Intron 3, Nonsense Mutation 2, 5'UTR 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMBT1 | c.933G>A p.W311* | Nonsense Mutation (SNP) | VAF 83/365 reads (23%) | catalogued as COSV57563965, COSV99042446; called by muse, mutect2, varscan2
- GRXCR1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs142351714, COSV67670862, COSV67672841; called by muse, mutect2, varscan2
- LCMT1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.223); catalogued as COSV101111787; called by muse, mutect2, varscan2
- MED12L | c.4034C>T p.S1345F | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV56400396; called by muse, mutect2, varscan2
- TEX14 | c.2245G>A p.E749K (on ENST00000240361 / NM_001201457.2; = p.E743K on NM_031272.5) | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1377165011, COSV99542437; called by muse, mutect2, varscan2
- THSD7B | c.3824G>A p.R1275Q (on ENST00000272643; = p.R1273Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs537759315, COSV55689505, COSV55712143; called by muse, mutect2, varscan2
- TTC25 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs530051771, COSV66367820; called by muse, mutect2, varscan2
- AHDC1 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 86/176 reads (49%) | called by muse, mutect2, varscan2
- ETFA | c.269-7T>A | Splice Region (SNP) | VAF 84/420 reads (20%) | called by muse, mutect2, varscan2
- ISG20L2 | c.1052C>G p.P351R | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ISG20L2 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 44/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ITGB4 | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 81/342 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MEX3C | c.1751C>T p.T584I | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- P2RX5 | c.968T>G p.M323R | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- SLC47A2 | c.844A>C p.S282R | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEDDM1 | c.673C>G p.H225D | Missense Mutation (SNP) | VAF 125/214 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ADPRM | c.285C>T p.D95= | Silent (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- GRIN2C | c.45C>T p.F15= | Silent (SNP) | VAF 132/294 reads (45%) | catalogued as rs770931049; called by muse, mutect2, varscan2
- ISG20L2 | c.411G>A p.Q137= | Silent (SNP) | VAF 52/383 reads (14%) | catalogued as rs779584129; called by muse, varscan2
- ISG20L2 | c.132G>A p.K44= | Silent (SNP) | VAF 71/515 reads (14%) | called by muse, mutect2, varscan2
- LHFPL5 | c.336C>T p.I112= | Silent (SNP) | VAF 64/340 reads (19%) | called by muse, mutect2, varscan2
- LUC7L3 | c.795G>A p.R265= | Silent (SNP) | VAF 37/164 reads (23%) | called by muse, mutect2, varscan2
- OR4P4 | c.378G>A p.K126= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as rs1213483798; called by muse, mutect2, varscan2
- PPARGC1B | c.2112G>A p.L704= | Silent (SNP) | VAF 68/184 reads (37%) | catalogued as rs759451326; called by muse, varscan2
- SEC23IP | c.2037A>T p.T679= | Silent (SNP) | VAF 51/228 reads (22%) | called by muse, mutect2, varscan2
- STAT2 | c.1137G>A p.L379= | Silent (SNP) | VAF 30/192 reads (16%) | catalogued as rs1227953202; called by muse, mutect2, varscan2
- C20orf197 | n.239G>A | RNA (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- DALRD3 | c.-14T>A | 5'UTR (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- FBXO11 | c.2006+87C>G | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- PGC | c.648-497C>T | Intron (SNP) | VAF 103/173 reads (60%) | called by muse, mutect2, varscan2
- PPP3R2 | c.-17G>A | 5'UTR (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100701305; called by muse, mutect2, varscan2
- TMEM132D | c.968+3198T>A | Intron (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
